Somatic mutation profile of cancer-model specimen HCM-CSHL-0384-D37-85P (3D Organoid; aliquot HCM-CSHL-0384-D37-85P-01D-A79M-36) from HCMI case HCM-CSHL-0384-D37, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubulovillous adenoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage 0; Tumor grade: GX; Age at diagnosis: 51.4 years (18,759 days).
Specimen HCM-CSHL-0384-D37-85P: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1792bae0-e1d0-4703-8e2d-d1fe4e36ae68.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0384-D37-10A (Blood Derived Normal), aliquot HCM-CSHL-0384-D37-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/078ea224-3b99-4e22-9b63-02cd1d35dcab

The open-access MAF lists 177 somatic variants for this specimen: 130 protein-altering or splice-affecting, 39 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 115, Silent 39, Frame Shift Del 4, Nonsense Mutation 4, Frame Shift Ins 4, Intron 4, 3'UTR 2, 5'Flank 2, Splice Region 1, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 131/330 reads (40%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- BRAF | c.1900G>A p.D634N (on ENST00000288602 / NM_001374244.1; = p.D594N on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 124/223 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs397516896, COSV56061673, COSV56106240, COSV56184663; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KCTD7 | c.591C>T p.C197= (on ENST00000275532; = p.R211* on NM_153033.5) | Silent (SNP) | VAF 182/780 reads (23%) | catalogued as rs750811871; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 175/397 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519946, COSV59042187, COSV59042498; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AMBN | c.296A>G p.Y99C | Missense Mutation (SNP) | VAF 119/268 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1329082409; called by muse, mutect2, varscan2
- APC | c.2821G>T p.E941* | Nonsense Mutation (SNP) | VAF 132/261 reads (51%) | catalogued as CM105842, COSV57327519; called by muse, mutect2, varscan2
- ARC | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 296/597 reads (50%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs780927796; called by muse, mutect2, varscan2
- ARHGEF40 | c.4459dup p.H1487Pfs*28 | Frame Shift Ins (INS) | VAF 166/393 reads (42%) | catalogued as rs758492903; called by mutect2, varscan2
- ATP8A2 | c.779G>A p.S260N | Missense Mutation (SNP) | VAF 106/229 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs747985877, COSV54937479; called by muse, mutect2, varscan2
- BCORL1 | c.1889G>A p.R630H | Missense Mutation (SNP) | VAF 299/458 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs143864671, COSV54391257; called by muse, mutect2, varscan2
- CAMSAP3 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 30/428 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.52); catalogued as rs375404607; called by muse, mutect2
- CCDC172 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 166/320 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781038484, COSV60937835; called by muse, mutect2, varscan2
- CCDC175 | c.1874G>A p.R625Q | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs199964220; called by muse, mutect2, varscan2
- CCDC22 | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 76/303 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.111); catalogued as rs781804126; called by muse, varscan2
- CELSR3 | c.7336G>A p.V2446M | Missense Mutation (SNP) | VAF 214/430 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs759534857, COSV99375101; called by muse, mutect2, varscan2
- CHRNB2 | c.889G>A p.V297I | Missense Mutation (SNP) | VAF 294/552 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1415028557; called by muse, mutect2, varscan2
- CLSTN3 | c.2386G>A p.V796M | Missense Mutation (SNP) | VAF 77/284 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as rs764251763; called by muse, mutect2, varscan2
- COL6A3 | c.2303G>A p.R768H | Missense Mutation (SNP) | VAF 239/454 reads (53%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); catalogued as rs575412915, COSV55101444; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.8765G>A p.R2922H | Missense Mutation (SNP) | VAF 178/354 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148539877; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK8 | c.4249G>A p.A1417T | Missense Mutation (SNP) | VAF 143/271 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.119); catalogued as rs1199786455; called by muse, mutect2, varscan2
- DSEL | c.968G>T p.W323L | Missense Mutation (SNP) | VAF 227/430 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100025713; called by muse, mutect2, varscan2
- EIF5B | c.2600C>T p.P867L | Missense Mutation (SNP) | VAF 130/262 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as rs751828370, COSV99177199; called by muse, mutect2, varscan2
- ERG | c.1121G>A p.R374H (on ENST00000398919 / NM_001243428.1; = p.R350H on NM_004449.4) | Missense Mutation (SNP) | VAF 248/467 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55728243, COSV55731950; called by muse, mutect2, varscan2
- FBN1 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 18/426 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as rs1305871580, COSV100355940; called by muse, mutect2
- FERMT2 | c.1045G>T p.A349S | Missense Mutation (SNP) | VAF 192/387 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58408179; called by muse, mutect2, varscan2
- FLOT2 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 143/399 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs763357953, COSV67528995; called by muse, mutect2, varscan2
- GALNT12 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 190/423 reads (45%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.75); catalogued as rs1256927785, COSV66662155; called by muse, mutect2, varscan2
- GALR2 | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 60/648 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.075); catalogued as rs1267812210; called by muse, mutect2
- GHRHR | c.164G>T p.C55F | Missense Mutation (SNP) | VAF 151/319 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs754386566; called by muse, mutect2, varscan2
- GRAMD1B | c.1472G>A p.R491Q | Missense Mutation (SNP) | VAF 183/368 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as rs780877280, COSV59205493; called by muse, mutect2, varscan2
- HADHB | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 55/463 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs780072612, CM119779, COSV58545823; called by muse, mutect2, varscan2
- HAPLN3 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 71/675 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs796566119, COSV100613705, COSV61370024; called by muse, mutect2, varscan2
- IGHM | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 16/476 reads (3%) | SIFT deleterious (0); catalogued as rs868946379; called by muse, mutect2
- IRX4 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 320/686 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770961282, COSV51474480, COSV51475669; called by muse, mutect2, varscan2
- ITGB5 | c.163G>A p.G55R | Missense Mutation (SNP) | VAF 47/244 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs771204149, COSV56148870; called by muse, mutect2, varscan2
- KCNB2 | c.515G>T p.C172F | Missense Mutation (SNP) | VAF 14/450 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as COSV101578775, COSV73052517; called by muse, mutect2
- LAMB4 | c.2389C>T p.R797C | Missense Mutation (SNP) | VAF 175/422 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs747592570, COSV52730857; called by muse, mutect2, varscan2
- MAN2A2 | c.24_25del p.C10Wfs*45 | Frame Shift Del (DEL) | VAF 174/440 reads (40%) | catalogued as rs768881302; called by mutect2, pindel, varscan2
- MAP1S | c.2561G>A p.R854Q | Missense Mutation (SNP) | VAF 56/862 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1436999132; called by muse, mutect2
- MMP15 | c.922G>A p.G308S | Missense Mutation (SNP) | VAF 247/512 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.068); catalogued as rs1037153021; called by muse, mutect2, varscan2
- MNT | c.1316C>T p.T439M | Missense Mutation (SNP) | VAF 26/721 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); catalogued as rs1190837157; called by muse, mutect2
- MRC1 | c.2770C>T p.R924* | Nonsense Mutation (SNP) | VAF 163/389 reads (42%) | catalogued as rs782352494; called by muse, mutect2, varscan2
- MYO15A | c.2483G>A p.R828Q | Missense Mutation (SNP) | VAF 242/656 reads (37%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.108); catalogued as rs1020210171; called by muse, mutect2, varscan2
- NCKAP1L | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 79/453 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779642333, COSV53206082; called by muse, mutect2, varscan2
- NLRP1 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 231/513 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.089); catalogued as rs200012608; called by muse, mutect2, varscan2
- NRXN1 | c.463G>A p.V155I | Missense Mutation (SNP) | VAF 19/623 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV68009283, COSV68026839; called by muse, mutect2
- OR2T4 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 328/644 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs756078095, COSV63544824; called by muse, mutect2, varscan2
- PCDH15 | c.1924G>A p.D642N | Missense Mutation (SNP) | VAF 86/197 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1455035148, COSV57321053; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHA13 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 35/705 reads (5%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as rs782534317, COSV56558969; called by muse, mutect2
- PCDHA5 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 125/257 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.021); catalogued as rs1554128615, COSV65350931; called by muse, mutect2, varscan2
- PDE10A | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 105/412 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866168774, COSV63092169; called by muse, mutect2
- PIK3CG | c.2657C>T p.T886M | Missense Mutation (SNP) | VAF 154/339 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as COSV63249761; called by muse, mutect2, varscan2
- PLEC | c.11833G>A p.G3945S (on ENST00000322810 / NM_201380.4; = p.G3835S on NM_000445.5) | Missense Mutation (SNP) | VAF 274/601 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as CM151763; called by muse, mutect2, varscan2
- PLXNB3 | c.2584C>T p.R862W | Missense Mutation (SNP) | VAF 49/369 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as rs782757118; called by muse, mutect2, varscan2
- PSME4 | c.2918G>A p.R973H | Missense Mutation (SNP) | VAF 144/284 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.326); catalogued as rs763188055; called by muse, mutect2, varscan2
- PTCHD4 | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 95/371 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs371181867; called by muse, mutect2, varscan2
- PTK6 | c.1207G>A p.G403S | Missense Mutation (SNP) | VAF 77/454 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as rs543091157; called by muse, mutect2, varscan2
- RAPSN | c.404G>A p.G135D | Missense Mutation (SNP) | VAF 239/510 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as rs759579462; called by muse, mutect2, varscan2
- RHOBTB1 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 38/390 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as rs201980179, COSV61957813; called by muse, mutect2
- RPL3 | c.199G>T p.V67L | Missense Mutation (SNP) | VAF 49/322 reads (15%) | SIFT tolerated (0.87); PolyPhen benign (0.062); catalogued as rs1207487016, COSV99335358; called by muse, mutect2, varscan2
- RSAD2 | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 186/381 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201120739; called by muse, mutect2, varscan2
- SLC13A5 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 283/546 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs201674669, COSV53421201; called by muse, mutect2, varscan2
- SLC24A2 | c.1471C>T p.R491C | Missense Mutation (SNP) | VAF 114/230 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1418543934, COSV53863537; called by muse, mutect2
- SLFN12 | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 175/365 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.848); catalogued as rs143225670; called by muse, mutect2, varscan2
- SOX11 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 225/428 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs750131174; called by muse, varscan2
- SP4 | c.2068C>T p.R690W | Missense Mutation (SNP) | VAF 29/356 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs869025250, COSV99755065; ClinVar: uncertain significance; called by muse, mutect2
- SPTAN1 | c.1420C>T p.R474W | Missense Mutation (SNP) | VAF 51/409 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV63989710; called by muse, mutect2, varscan2
- STX10 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 220/433 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.307); catalogued as rs751947745, COSV52834013; called by muse, mutect2, varscan2
- TJP1 | c.3235C>T p.R1079* | Nonsense Mutation (SNP) | VAF 250/526 reads (48%) | catalogued as COSV62043997; called by muse, varscan2
- TOR4A | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 394/838 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.082); catalogued as rs756370946; called by muse, mutect2, varscan2
- TRIM7 | c.1352C>T p.S451L | Missense Mutation (SNP) | VAF 324/681 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as rs772954194; called by muse, mutect2, varscan2
- TTN | c.5774T>G p.V1925G (on ENST00000591111; = p.V1879G on NM_003319.4) | Missense Mutation (SNP) | VAF 180/409 reads (44%) | PolyPhen probably damaging (0.998); catalogued as COSV100593866; called by muse, mutect2, varscan2
- TULP4 | c.2920G>T p.A974S | Missense Mutation (SNP) | VAF 212/658 reads (32%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV65577334; called by muse, mutect2, varscan2
- ZC3H4 | c.2335G>C p.E779Q | Missense Mutation (SNP) | VAF 249/632 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756950439, COSV53410194; called by muse, mutect2, varscan2
- ZNF804A | c.2852del p.P951Lfs*34 | Frame Shift Del (DEL) | VAF 79/269 reads (29%) | catalogued as COSV56435462; called by mutect2, pindel, varscan2
- ZWILCH | c.1387C>A p.R463S | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV57181944; called by muse, mutect2
- ALPP | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 252/1071 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- ARHGEF4 | c.1792C>A p.L598I | Missense Mutation (SNP) | VAF 244/508 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.42); called by mutect2, varscan2
- AWAT1 | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2
- BASP1 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 289/569 reads (51%) | SIFT tolerated (0.88); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BCHE | c.140C>A p.T47K | Missense Mutation (SNP) | VAF 56/330 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRF1 | c.1935G>C p.E645D | Missense Mutation (SNP) | VAF 169/543 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDK11B | c.1731G>T p.K577N | Missense Mutation (SNP) | VAF 26/236 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CLCA4 | c.1210G>C p.D404H | Missense Mutation (SNP) | VAF 15/349 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.478); called by muse, mutect2
- CPSF6 | c.720_749del p.L241_P250del | In Frame Del (DEL) | VAF 130/373 reads (35%) | called by mutect2, varscan2
- CSMD3 | c.2229T>A p.N743K (on ENST00000297405 / NM_001363185.1; = p.N639K on NM_052900.3) | Missense Mutation (SNP) | VAF 137/287 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- D2HGDH | c.855C>A p.G285= | Splice Region (SNP) | VAF 148/298 reads (50%) | called by muse, mutect2, varscan2
- DAW1 | c.84G>C p.K28N | Missense Mutation (SNP) | VAF 114/272 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); called by muse, mutect2
- DYNC2H1 | c.2641G>T p.D881Y | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ETV4 | c.46T>C p.Y16H | Missense Mutation (SNP) | VAF 264/541 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- FBXL4 | c.887C>T p.T296I | Missense Mutation (SNP) | VAF 61/198 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- FOXF1 | c.784G>A p.V262I | Missense Mutation (SNP) | VAF 96/638 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.194); called by muse, varscan2
- GATM | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 44/557 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.432); called by muse, mutect2
- GIPC3 | c.3124G>A p.G1042R | Missense Mutation (SNP) | VAF 57/400 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HELLS | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 123/273 reads (45%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- HMCN1 | c.232C>G p.L78V | Missense Mutation (SNP) | VAF 146/336 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- INKA1 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 287/583 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JMJD1C | c.1909A>C p.K637Q | Missense Mutation (SNP) | VAF 169/355 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- KCNH7 | c.2861A>G p.D954G | Missense Mutation (SNP) | VAF 24/450 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- KIF17 | c.2531T>G p.L844W | Missense Mutation (SNP) | VAF 244/244 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KLHL34 | c.208A>T p.I70F | Missense Mutation (SNP) | VAF 24/402 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- KRT72 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 299/621 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- MAP3K19 | c.1165A>G p.T389A | Missense Mutation (SNP) | VAF 32/420 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- MMRN1 | c.2875C>A p.L959I | Missense Mutation (SNP) | VAF 107/374 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- MYH4 | c.985C>T p.Q329* | Nonsense Mutation (SNP) | VAF 96/291 reads (33%) | called by muse, mutect2, varscan2
- NALCN | c.2993A>T p.K998I | Missense Mutation (SNP) | VAF 54/448 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- NDNF | c.508G>T p.D170Y | Missense Mutation (SNP) | VAF 233/445 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NKAIN4 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 161/463 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- OR2B3 | c.434C>A p.A145E | Missense Mutation (SNP) | VAF 36/724 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2
- OR4A8 | c.833C>A p.P278H | Missense Mutation (SNP) | VAF 11/244 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.324); called by muse, mutect2
- OR6C65 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 224/225 reads (100%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- PAPPA2 | c.3128_3135del p.P1043Lfs*49 | Frame Shift Del (DEL) | VAF 106/325 reads (33%) | called by mutect2, pindel, varscan2
- PCNT | c.733C>T p.L245F | Missense Mutation (SNP) | VAF 35/352 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- PDLIM1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 17/510 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- PKHD1 | c.8791C>A p.H2931N | Missense Mutation (SNP) | VAF 11/284 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- PKHD1 | c.4825G>T p.D1609Y | Missense Mutation (SNP) | VAF 182/482 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- PLXNA1 | c.2578C>T p.R860C | Missense Mutation (SNP) | VAF 18/624 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2
- POLR3A | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 25/537 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.314); called by muse, mutect2
- RFNG | c.67C>A p.L23M | Missense Mutation (SNP) | VAF 52/97 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- RORB | c.828G>C p.Q276H (on ENST00000396204 / NM_001365023.1; = p.Q265H on NM_006914.4) | Missense Mutation (SNP) | VAF 179/358 reads (50%) | SIFT tolerated (0.46); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SORBS1 | c.1420dup p.L474Pfs*9 (on ENST00000361941 / NM_001034954.2; = p.L264Pfs*9 on NM_006434.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 25/253 reads (10%) | called by mutect2, pindel, varscan2
- SORCS3 | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 70/751 reads (9%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.001); called by muse, mutect2
- TCF7L2 | c.979_983dup p.G329Mfs*24 (on ENST00000355995 / NM_001367943.1; = p.G306Mfs*24 on NM_030756.5) | Frame Shift Ins (INS) | VAF 166/408 reads (41%) | called by mutect2, varscan2
- TEX13C | c.2257C>G p.L753V | Missense Mutation (SNP) | VAF 254/283 reads (90%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- TMCO5A | c.506A>C p.K169T | Missense Mutation (SNP) | VAF 81/204 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TTN | c.15986T>G p.I5329S (on ENST00000591111; = p.I4402S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/352 reads (18%) | PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZBTB4 | c.82C>T p.L28F | Missense Mutation (SNP) | VAF 286/609 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZFX | c.2086G>A p.D696N | Missense Mutation (SNP) | VAF 50/301 reads (17%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- ZMYM4 | c.786G>A p.M262I | Missense Mutation (SNP) | VAF 131/314 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF598 | c.1957_1973del p.L653Vfs*62 | Frame Shift Del (DEL) | VAF 236/560 reads (42%) | called by mutect2, varscan2
- ZNF837 | c.362G>A p.G121D | Missense Mutation (SNP) | VAF 73/721 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2
- ADGRE2 | c.276C>T p.Y92= | Silent (SNP) | VAF 251/530 reads (47%) | catalogued as rs376023757; called by muse, mutect2, varscan2
- ANKRD20A4P | c.546G>C p.V182= | Silent (SNP) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- ANO6 | c.1533G>A p.T511= | Silent (SNP) | VAF 36/428 reads (8%) | catalogued as rs758140092, COSV100262903; called by muse, mutect2
- ASTN2 | c.2952A>T p.P984= (on ENST00000313400 / NM_001365069.1; = p.P933= on NM_014010.5) | Silent (SNP) | VAF 256/550 reads (47%) | called by muse, mutect2, varscan2
- BCAM | c.846C>T p.R282= | Silent (SNP) | VAF 331/666 reads (50%) | catalogued as rs771831123, COSV54302776; called by muse, mutect2, varscan2
- BMP7 | c.30G>A p.A10= | Silent (SNP) | VAF 200/515 reads (39%) | called by muse, varscan2
- C2CD6 | c.150G>T p.S50= | Silent (SNP) | VAF 236/417 reads (57%) | called by muse, mutect2, varscan2
- CFAP54 | c.6606T>C p.F2202= | Silent (SNP) | VAF 189/378 reads (50%) | called by muse, mutect2, varscan2
- CHD4 | c.5658G>T p.L1886= (on ENST00000357008 / NM_001363606.2; = p.L1896= on NM_001273.5) | Silent (SNP) | VAF 50/546 reads (9%) | called by muse, mutect2
- CHRNB4 | c.414C>T p.N138= | Silent (SNP) | VAF 71/417 reads (17%) | catalogued as rs55851389; called by muse, mutect2
- CLCN2 | c.888C>T p.N296= | Silent (SNP) | VAF 27/316 reads (9%) | called by muse, mutect2
- CSMD1 | c.624C>T p.C208= | Silent (SNP) | VAF 23/385 reads (6%) | catalogued as rs529835549, COSV68203262; called by muse, mutect2
- DGCR8 | c.2280C>T p.S760= | Silent (SNP) | VAF 190/410 reads (46%) | catalogued as rs374499450; called by muse, mutect2, varscan2
- DOK2 | c.207C>T p.A69= | Silent (SNP) | VAF 283/587 reads (48%) | catalogued as rs757512119; called by muse, mutect2, varscan2
- EVC | c.885C>G p.T295= | Silent (SNP) | VAF 136/322 reads (42%) | catalogued as COSV53836531; called by muse, mutect2, varscan2
- F2 | c.1830G>A p.K610= | Silent (SNP) | VAF 170/331 reads (51%) | called by muse, mutect2, varscan2
- FBXO40 | c.1338C>T p.D446= | Silent (SNP) | VAF 213/441 reads (48%) | catalogued as rs764170628; called by muse, mutect2, varscan2
- FOXG1 | c.246G>A p.P82= | Silent (SNP) | VAF 67/130 reads (52%) | called by muse, varscan2
- GATA3 | c.1257C>A p.P419= | Silent (SNP) | VAF 339/655 reads (52%) | catalogued as rs768238506; called by muse, mutect2, varscan2
- GPR180 | c.264T>G p.G88= | Silent (SNP) | VAF 145/302 reads (48%) | called by muse, mutect2, varscan2
- HNRNPUL1 | c.117C>T p.A39= | Silent (SNP) | VAF 126/736 reads (17%) | called by muse, mutect2, varscan2
- KIF18A | c.564C>T p.V188= | Silent (SNP) | VAF 30/450 reads (7%) | catalogued as rs267602838, COSV54188341; called by muse, mutect2
- MYH13 | c.1845G>A p.S615= | Silent (SNP) | VAF 38/487 reads (8%) | catalogued as rs778246169, COSV52822114, COSV52842878; called by muse, mutect2
- PCDHB2 | c.1986G>A p.V662= | Silent (SNP) | VAF 41/979 reads (4%) | called by muse, mutect2
- PCDHB7 | c.576C>T p.P192= | Silent (SNP) | VAF 31/352 reads (9%) | catalogued as COSV50781338, COSV50809909; called by muse, mutect2
- PCDHB8 | c.567C>T p.G189= | Silent (SNP) | VAF 109/362 reads (30%) | called by muse, mutect2, varscan2
- PCDHGA10 | c.1623C>T p.S541= | Silent (SNP) | VAF 266/506 reads (53%) | called by muse, mutect2, varscan2
- PCDHGA5 | c.795C>T p.T265= | Silent (SNP) | VAF 165/452 reads (37%) | catalogued as COSV54046688; called by muse, mutect2, varscan2
- PCDHGA6 | c.1869G>A p.T623= | Silent (SNP) | VAF 361/754 reads (48%) | catalogued as rs1032808913; called by muse, mutect2, varscan2
- PPP1R2B | c.84G>A p.S28= | Silent (SNP) | VAF 244/497 reads (49%) | catalogued as rs778681228, COSV70372913; called by muse, mutect2, varscan2
- PRKCSH | c.1365C>T p.P455= | Silent (SNP) | VAF 198/432 reads (46%) | catalogued as rs368834600; called by muse, mutect2, varscan2
- RNFT2 | c.186C>A p.G62= | Silent (SNP) | VAF 278/575 reads (48%) | called by muse, mutect2, varscan2
- RTP1 | c.378C>T p.R126= | Silent (SNP) | VAF 58/687 reads (8%) | catalogued as rs750359975, COSV56619041; called by muse, mutect2
- SETBP1 | c.996C>A p.G332= | Silent (SNP) | VAF 159/322 reads (49%) | called by muse, mutect2, varscan2
- TMEM175 | c.42G>A p.P14= | Silent (SNP) | VAF 237/506 reads (47%) | catalogued as rs747420455, COSV53279605; called by muse, mutect2, varscan2
- TRBV19 | c.144C>T p.H48= | Silent (SNP) | VAF 161/379 reads (42%) | catalogued as rs17263; called by muse, mutect2, varscan2
- WDR81 | c.4755C>A p.I1585= (on ENST00000409644 / NM_001163809.2; = p.I534= on NM_152348.4) | Silent (SNP) | VAF 96/882 reads (11%) | called by muse, mutect2, varscan2
- XPO5 | c.2334G>A p.A778= | Silent (SNP) | VAF 102/260 reads (39%) | catalogued as rs745435024, COSV54827894; called by muse, mutect2, varscan2
- ACSS1 | c.*861A>G | 3'UTR (SNP) | VAF 38/340 reads (11%) | called by muse, mutect2, varscan2
- DOCK8 | c.53+342G>A | Intron (SNP) | VAF 209/432 reads (48%) | catalogued as rs201097337, COSV101213736, COSV66688303; called by muse, mutect2, varscan2
- GRIA1 | c.82+1273C>A | Intron (SNP) | VAF 40/505 reads (8%) | catalogued as rs768805842; called by muse, mutect2
- KCNK12 | c.*8500C>A | 3'UTR (SNP) | VAF 181/372 reads (49%) | catalogued as COSV100010031; called by muse, mutect2, varscan2
- NRG1 | chr8:31640044 C>T | 5'Flank (SNP) | VAF 131/222 reads (59%) | called by muse, mutect2, varscan2
- VIPR2 | c.152-7447A>T | Intron (SNP) | VAF 185/410 reads (45%) | called by muse, mutect2, varscan2
- ZNF578 | chr19:52451208 A>C | 5'Flank (SNP) | VAF 44/227 reads (19%) | called by muse, mutect2, varscan2
- ZNF875 | c.314-4147G>A | Intron (SNP) | VAF 48/347 reads (14%) | called by muse, mutect2, varscan2
